Somatic mutation profile of tumor specimen C3N-03028-01 (aliquot CPT0226440006) from CPTAC case C3N-03028, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 59.9 years (21,881 days).
Specimen C3N-03028-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9007c29-8294-4a78-a729-6a66ea566190.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03028-31 (Blood Derived Normal), aliquot CPT0226480002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c93f89c3-0d4a-4520-8c42-e324d8735bcb

The open-access MAF lists 126 somatic variants for this specimen: 81 protein-altering or splice-affecting, 31 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 31, Intron 9, Nonsense Mutation 5, Frame Shift Ins 4, Frame Shift Del 4, 3'UTR 3, In Frame Del 2, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.476C>A p.A159D | Missense Mutation (SNP) | VAF 241/488 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52674926, COSV52693942, COSV52759722; called by muse, mutect2, varscan2
- AAGAB | c.176A>G p.N59S | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as rs148784657; called by muse, mutect2, varscan2
- ALDH1L1 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 46/470 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs895519887; called by muse, mutect2
- ALPP | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 69/391 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs778841965, COSV67396862; called by muse, mutect2, varscan2
- AQP5 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs766801870, COSV53311765; called by muse, mutect2, varscan2
- ASTN2 | c.1199C>T p.T400M (on ENST00000313400 / NM_001365069.1; = p.T349M on NM_014010.5) | Missense Mutation (SNP) | VAF 184/376 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs143162948; called by muse, mutect2, varscan2
- CACNA1B | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 70/439 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs762469618, COSV53129810; called by muse, mutect2, varscan2
- CASP8 | c.1301C>T p.P434L (on ENST00000432109 / NM_033355.3; = p.P451L on NM_001228.4) | Missense Mutation (SNP) | VAF 88/293 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV51852709; called by muse, mutect2, varscan2
- CDH18 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1469399669, COSV56911322; called by muse, mutect2
- CLASP2 | c.562A>G p.I188V | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1158639187; called by muse, mutect2, varscan2
- CLASRP | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55514741; called by muse, mutect2, varscan2
- COL1A2 | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 384/1130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746504964, COSV51956931; called by muse, mutect2, varscan2
- GAL | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 78/837 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.176); catalogued as rs530498888; called by muse, mutect2
- HDLBP | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as rs556914078, COSV100191654; called by muse, mutect2, varscan2
- HIP1R | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 172/496 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1195344507; called by muse, mutect2, varscan2
- IFRD1 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 72/429 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1218634159, COSV104374934; called by muse, mutect2, varscan2
- IRAK2 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 68/356 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs780730043; called by muse, mutect2, varscan2
- KCNA6 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1479006895; called by muse, mutect2, varscan2
- KCNH3 | c.2966G>A p.R989Q | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs143655453; called by muse, mutect2, varscan2
- KCNH5 | c.2372A>G p.D791G | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs548465461; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA0513 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs142747183; called by muse, mutect2, varscan2
- MAGEA3 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1202032617, COSV64756205; called by muse, mutect2, varscan2
- MEIG1 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 47/326 reads (14%) | catalogued as rs367880346; called by muse, mutect2, varscan2
- NLRP10 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 57/325 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.418); catalogued as rs1186100956, COSV60780770; called by muse, mutect2, varscan2
- OCA2 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 48/1186 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.145); catalogued as rs757923752, COSV62345291; called by muse, mutect2
- PAK1IP1 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 40/576 reads (7%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs190974202, COSV101093325; called by muse, mutect2
- PDK4 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 12/114 reads (11%) | catalogued as rs181545860; called by muse, mutect2
- PPP1R9A | c.2387A>G p.E796G | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56902855; called by muse, mutect2
- PRDM9 | c.428G>A p.S143N | Missense Mutation (SNP) | VAF 27/317 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.227); catalogued as COSV57009819; called by muse, mutect2
- PRL | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 71/316 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1306019408; called by muse, mutect2, varscan2
- PSAT1 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 65/503 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.18); catalogued as rs745532660, COSV61303305; called by muse, mutect2, varscan2
- RGPD4 | c.3055G>A p.G1019S | Missense Mutation (SNP) | VAF 204/881 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs766321992, COSV61745686, COSV61749823; called by muse, mutect2, varscan2
- SETD1A | c.3848C>T p.S1283L | Missense Mutation (SNP) | VAF 91/724 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1487215730, COSV99354048; called by muse, mutect2, varscan2
- SH3TC1 | c.3127G>C p.E1043Q | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV55284022; called by muse, mutect2
- SKA3 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT tolerated (0.96); PolyPhen benign (0.006); catalogued as rs1281446078; called by muse, mutect2
- SLC22A4 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 94/705 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as rs199535716, COSV52359606; called by muse, mutect2, varscan2
- SLC26A4 | c.1427A>T p.K476M | Missense Mutation (SNP) | VAF 78/524 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55919842; called by muse, mutect2, varscan2
- SLC45A4 | c.1423G>A p.G475R (on ENST00000517878 / NM_001286646.2; = p.G424R on NM_001080431.2) | Missense Mutation (SNP) | VAF 70/601 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs1256701052; called by muse, mutect2, varscan2
- TAF4 | c.1721G>A p.R574H | Missense Mutation (SNP) | VAF 73/645 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs888972140, COSV99433948; called by muse, mutect2, varscan2
- TLR1 | c.689G>A p.C230Y | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1424844701; called by muse, mutect2
- TMEM132C | c.3015C>G p.C1005W | Missense Mutation (SNP) | VAF 81/579 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.683); catalogued as COSV100176912, COSV59423395; called by muse, mutect2, varscan2
- TPMT | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 40/346 reads (12%) | catalogued as rs761990479, COSV59428716; called by muse, mutect2, varscan2
- TTN | c.87827T>C p.V29276A (on ENST00000591111; = p.V21852A on NM_003319.4) | Missense Mutation (SNP) | VAF 117/340 reads (34%) | PolyPhen benign (0.006); catalogued as rs748545482; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBE3C | c.148A>G p.I50V | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs761130106; called by muse, mutect2, varscan2
- UBTF | c.761A>G p.K254R | Missense Mutation (SNP) | VAF 43/344 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.673); catalogued as COSV57186352; called by muse, mutect2, varscan2
- WRNIP1 | c.388C>A p.R130S | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.139); catalogued as COSV66355895; called by muse, mutect2, varscan2
- ABCA10 | c.4576G>A p.D1526N | Missense Mutation (SNP) | VAF 54/276 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- ADGB | c.2937T>G p.Y979* | Nonsense Mutation (SNP) | VAF 21/135 reads (16%) | called by muse, mutect2, varscan2
- AHNAK | c.11577del p.K3860Nfs*7 | Frame Shift Del (DEL) | VAF 88/810 reads (11%) | called by mutect2, varscan2
- BTBD7 | c.3346G>C p.G1116R | Missense Mutation (SNP) | VAF 164/283 reads (58%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- CEP43 | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 50/432 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CRISP2 | c.626A>G p.D209G | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DLX3 | c.385G>C p.V129L | Missense Mutation (SNP) | VAF 148/655 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DNHD1 | c.7605_7623del p.L2536Sfs*27 | Frame Shift Del (DEL) | VAF 64/462 reads (14%) | called by mutect2, pindel, varscan2
- DSP | c.1462_1464del p.N488del | In Frame Del (DEL) | VAF 111/656 reads (17%) | called by pindel, varscan2
- FGD5 | c.3912_3915dup p.A1306Qfs*36 | Frame Shift Ins (INS) | VAF 49/333 reads (15%) | called by mutect2, pindel, varscan2
- FIGNL2 | c.1699del p.L567Cfs*123 | Frame Shift Del (DEL) | VAF 189/643 reads (29%) | called by mutect2, pindel, varscan2
- HOXB6 | c.577dup p.W193Lfs*123 | Frame Shift Ins (INS) | VAF 231/1037 reads (22%) | called by mutect2, pindel, varscan2
- IGHG2 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 300/982 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, varscan2
- KIF7 | c.3663G>C p.R1221S | Missense Mutation (SNP) | VAF 132/1003 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LINGO2 | c.950T>A p.F317Y | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MGAT5B | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 81/332 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- MRPL55 | c.221dup p.M74Ifs*14 | Frame Shift Ins (INS) | VAF 93/623 reads (15%) | called by mutect2, pindel, varscan2
- MRTFA | c.1085T>C p.I362T | Missense Mutation (SNP) | VAF 59/375 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, varscan2
- NPHP3 | c.3738A>C p.L1246F | Missense Mutation (SNP) | VAF 13/329 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2
- NUP133 | c.3203A>T p.D1068V | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- OR10A6 | c.72G>C p.Q24H | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- PCLO | c.11554G>T p.G3852C | Missense Mutation (SNP) | VAF 121/496 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PTK2 | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 168/602 reads (28%) | called by muse, mutect2, varscan2
- RIMS2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 15/211 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.532); called by muse, mutect2
- SLC39A4 | c.727C>A p.H243N (on ENST00000301305 / NM_001374839.1; = p.H218N on NM_017767.3) | Missense Mutation (SNP) | VAF 60/1016 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); called by muse, mutect2
- SOS1 | c.3901C>T p.H1301Y | Missense Mutation (SNP) | VAF 77/439 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SP4 | c.226C>G p.P76A | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SUSD1 | c.175dup p.C59Lfs*15 | Frame Shift Ins (INS) | VAF 105/246 reads (43%) | called by mutect2, pindel, varscan2
- TASOR2 | c.4645G>A p.G1549R | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TRIM60 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- UBR4 | c.12102C>A p.N4034K | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UNCX | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 116/795 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by mutect2, varscan2
- VPS13B | c.105_107del p.V36del | In Frame Del (DEL) | VAF 115/438 reads (26%) | called by mutect2, pindel, varscan2
- XCR1 | c.162_171del p.W54* | Frame Shift Del (DEL) | VAF 123/390 reads (32%) | called by mutect2, pindel, varscan2
- ZFP69 | c.890A>C p.K297T | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABCC2 | c.2793G>A p.L931= | Silent (SNP) | VAF 128/620 reads (21%) | catalogued as COSV64986901; called by muse, mutect2, varscan2
- ANO4 | c.2343T>A p.S781= (on ENST00000392977 / NM_001286615.2; = p.S746= on NM_178826.4) | Silent (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- ASXL1 | c.2766T>C p.V922= | Silent (SNP) | VAF 198/838 reads (24%) | called by muse, mutect2, varscan2
- ATP13A2 | c.3339C>T p.D1113= | Silent (SNP) | VAF 99/747 reads (13%) | called by muse, mutect2, varscan2
- CNGA3 | c.1275G>A p.Q425= | Silent (SNP) | VAF 229/903 reads (25%) | called by muse, mutect2, varscan2
- CTBP2 | c.381G>A p.P127= | Silent (SNP) | VAF 81/530 reads (15%) | catalogued as rs201542036; called by muse, mutect2, varscan2
- DNAH11 | c.4425C>T p.Y1475= | Silent (SNP) | VAF 24/211 reads (11%) | catalogued as rs373706559; called by muse, mutect2, varscan2
- EDEM1 | c.991C>A p.R331= | Silent (SNP) | VAF 46/127 reads (36%) | called by muse, mutect2
- EPS15 | c.1986T>C p.S662= | Silent (SNP) | VAF 18/160 reads (11%) | called by muse, mutect2, varscan2
- FGFR3 | c.807C>T p.S269= | Silent (SNP) | VAF 37/445 reads (8%) | catalogued as rs199614237; ClinVar: likely benign; called by muse, mutect2
- FRS3 | c.861C>T p.Y287= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs758518502, COSV52484710; called by muse, mutect2, varscan2
- GSX2 | c.684T>A p.S228= | Silent (SNP) | VAF 67/471 reads (14%) | called by muse, mutect2, varscan2
- LAMA5 | c.1428G>A p.S476= | Silent (SNP) | VAF 58/233 reads (25%) | catalogued as rs375000484; called by muse, mutect2, varscan2
- MAGEF1 | c.177G>A p.A59= | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as rs1327190076, COSV100510898, COSV58633728; called by muse, mutect2
- MYH7B | c.4140C>A p.A1380= | Silent (SNP) | VAF 94/337 reads (28%) | catalogued as COSV99328699; called by muse, mutect2, varscan2
- OPCML | c.909G>A p.G303= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as rs758637223, COSV100106111; called by muse, mutect2
- OR1A2 | c.609C>T p.V203= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs150553361; called by muse, mutect2, varscan2
- PALLD | c.1311C>T p.A437= | Silent (SNP) | VAF 101/703 reads (14%) | called by muse, mutect2, varscan2
- PKD2L1 | c.1332C>G p.V444= | Silent (SNP) | VAF 76/667 reads (11%) | called by muse, mutect2, varscan2
- PRPF31 | c.12A>C p.A4= | Silent (SNP) | VAF 112/823 reads (14%) | called by muse, mutect2, varscan2
- RBM14 | c.708C>G p.T236= | Silent (SNP) | VAF 87/817 reads (11%) | called by muse, mutect2, varscan2
- RHO | c.501C>T p.C167= | Silent (SNP) | VAF 703/1459 reads (48%) | catalogued as rs751280060, CM044036; called by muse, mutect2, varscan2
- RPS6KA3 | c.1497T>G p.G499= | Silent (SNP) | VAF 44/112 reads (39%) | called by muse, mutect2, varscan2
- RXFP3 | c.597C>T p.G199= | Silent (SNP) | VAF 65/466 reads (14%) | catalogued as rs1462788994, COSV100347284, COSV57507670; called by muse, mutect2, varscan2
- SBF1 | c.2919G>T p.V973= | Silent (SNP) | VAF 54/320 reads (17%) | catalogued as rs777197676; called by muse, mutect2, varscan2
- TACO1 | c.339C>T p.R113= | Silent (SNP) | VAF 242/841 reads (29%) | catalogued as rs1194119476; called by muse, mutect2, varscan2
- TWNK | c.570C>T p.L190= | Silent (SNP) | VAF 163/1430 reads (11%) | catalogued as COSV52973101; called by muse, mutect2, varscan2
- UBN2 | c.153G>A p.P51= | Silent (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- XRN1 | c.4005A>G p.S1335= | Silent (SNP) | VAF 108/258 reads (42%) | called by muse, mutect2, varscan2
- ZNF331 | c.33A>T p.V11= | Silent (SNP) | VAF 105/381 reads (28%) | called by muse, mutect2, varscan2
- ZNF577 | c.1218G>A p.E406= | Silent (SNP) | VAF 105/368 reads (29%) | catalogued as rs1276403224; called by muse, mutect2, varscan2
- AAMDC | c.-18-1243dup | Intron (INS) | VAF 13/95 reads (14%) | called by mutect2, pindel, varscan2
- APOC1P1 | n.307C>G | RNA (SNP) | VAF 35/232 reads (15%) | called by muse, mutect2, varscan2
- ASPH | c.254-1403G>T | Intron (SNP) | VAF 28/209 reads (13%) | called by muse, mutect2, varscan2
- CLRN1 | c.*519C>T | 3'UTR (SNP) | VAF 32/177 reads (18%) | catalogued as rs916738545; called by muse, mutect2, varscan2
- FOXP2 | c.-318dup | 5'UTR (INS) | VAF 20/112 reads (18%) | called by mutect2, pindel, varscan2
- MAGED1 | c.46-298G>A | Intron (SNP) | VAF 9/25 reads (36%) | catalogued as COSV58515004; called by muse, mutect2, varscan2
- MYRF | c.46+4412del | Intron (DEL) | VAF 64/549 reads (12%) | called by mutect2, pindel, varscan2
- NCOR1 | c.6679+31T>G | Intron (SNP) | VAF 10/98 reads (10%) | called by muse, varscan2
- NOMO1 | c.*377C>A | 3'UTR (SNP) | VAF 40/686 reads (6%) | catalogued as COSV55059463; called by muse, mutect2
- OBSCN | c.18662-2944G>A | Intron (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2
- PTPRC | c.3645+32C>T | Intron (SNP) | VAF 51/322 reads (16%) | catalogued as rs755781612; called by muse, mutect2, varscan2
- RARRES2 | c.*97C>A | 3'UTR (SNP) | VAF 56/370 reads (15%) | catalogued as COSV56231903; called by muse, mutect2, varscan2
- SCGB2A2 | c.243+31A>G | Intron (SNP) | VAF 153/353 reads (43%) | called by muse, mutect2, varscan2
- ZNF584 | c.292+242C>T | Intron (SNP) | VAF 106/400 reads (27%) | called by muse, mutect2, varscan2
